Somatic mutation profile of tumor specimen TARGET-30-PARSVF-01A (aliquot TARGET-30-PARSVF-01A-01D) from TARGET case TARGET-30-PARSVF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.6 years (964 days).
Specimen TARGET-30-PARSVF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d2076a4-06a6-4c85-a594-a6a040fe0492.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARSVF-10A (Blood Derived Normal), aliquot TARGET-30-PARSVF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cefdca7e-c360-496f-978b-fe3a3032956d

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH2 | c.4662G>T p.E1554D | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV55445326, COSV55451139; called by muse, mutect2, varscan2
- COL5A3 | c.3180G>T p.L1060= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV53421401; called by muse, mutect2, varscan2
- DPP6 | c.-262C>A | 5'UTR (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
